TCGA case TCGA-DM-A1HA — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56c8b812-ca8e-4eb2-b0fe-f264316789bf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Israel; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2000; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,600 days (7.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 17.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 2,600.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KRAS mutation, nos: Positive; Mutation codon: 12.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 163 cm; BMI: 25.2.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DM-A1HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-DM-A1HA-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DM-A1HA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DM-A1HA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: Yes; History colon polyps: Yes; Colon polyps at procurement indicator: Yes.
- Follow-up form: New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,000 days; disease-specific survival: no event (censored), 4,000 days; progression-free interval: no event (censored), 4,000 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DM-A1HA-01A-11D-A151-01): tumor purity 0.93, ploidy 1.95, whole-genome doublings 0.
